Surgical pathology report (de-identified scan), TCGA case TCGA-4B-A93V, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-4B-A93V-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: F	Date Collected: [REDACTED]
MRN: [REDACTED]	Date Received: [REDACTED]
Requested by: [REDACTED]	Date Reported: [REDACTED]
Copy to: [REDACTED]	

Clinical Data: Right lung cancer, total cancer care

FINAL PATHOLOGIC DIAGNOSIS

1. Right lower lobe of lung, lobectomy (201.5 grams):
Adenocarcinoma. See Synoptic Report.
2. Right peribronchial lymph node, excision:
One lymph node is negative for malignancy (0/1).
3. Right paratracheal lymph node, excision:
Two lymph nodes are negative for malignancy (0/2).

IADG-3

Adenocarcinoma NOS 8140/3
Site: R Lung, Lower Lobe C54.3
JWS/26/14

SYNOPTIC REPORT

Tumor site:	Right lower lobe
Specimen integrity:	Intact
Tumor size:	3 cm
Tumor focality:	Unifocal
Histologic type:	Adenocarcinoma
Histologic grade:	Moderate to poorly differentiated (G2-G3)
Visceral pleural invasion:	Not identified
Microscopic extent of tumor:	Tumor surrounded by lung, without evidence of invasion more proximal than the lobar bronchus
Margins:	Uninvolved by invasive carcinoma
Bronchial margin:	Negative for tumor
Vascular margin:	Negative for tumor
Parenchymal margin:	Negative for tumor
Treatment effect:	Not identified
Lymph/Vascular invasion:	Absent
Regional lymph nodes:	Three lymph nodes are negative for tumor (0/3)
Pathologic Tumor Stage:	pT1b pN0

Comment: Sections from the tumor are remarkable for predominantly moderately differentiated adenocarcinoma. More solid areas are identified, and therefore, immunohistochemical stains for cytokeratin-7, cytokeratin-5/6, TTF-1, and p63 were performed to evaluate for a mixed subtype. The tumor is positive for cytokeratin-7 and TTF-1 only, confirming an adenocarcinoma. Molecular studies may be indicated.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

Pathologist, Electronic Signature

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

1. **Right lower lobe of lung:** Received initially in the fresh state labeled "right lower lobe of lung" is a 201.5 gram, 15.5 x 11.5 x 3.5 cm lung lobe. The pleura displays a abundant anthracotic pigment. Sectioning reveals a well circumscribed 3 cm in greatest dimension firm tumor within the anterior basal segment. The tumor lies 2.8 cm from the bronchial margin of resection. The tumor abuts, but does not penetrate through the overlying pleura. The remaining parenchyma is spongy red-brown. No hilar lymph nodes are identified. The pleura overlying the tumor is inked black. Representative sections are submitted in 5 cassettes as A-B tumor to include overlying pleura, C tumor to include uninvolved lung parenchyma, D normal lung parenchyma, E bronchial and vascular margins.
2. **Right peribronchial lymph node:** In formalin labeled "right peribronchial lymph node" is a 0.7 cm lymph node which is submitted in toto in one cassette.
3. **Right paratracheal lymph node:** In formalin labeled "paratracheal lymph node" are 2 lymph node fragments aggregating 1.2 cm which is submitted in toto in one cassette.

CPT CODE(S):

88342 x4, 88309, 88305 x2

ICD-9 CODE(S):

[1625]

FACILITY:

END OF REPORT

Source: NCI Genomic Data Commons file e46ebcf6-0bb3-4459-87b0-70deacf88e2f (TCGA-4B-A93V.3723B92A-EFB6-4239-9D26-B88AF56252CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).